CCDI case PBCDRK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/ceb3ea78-22b6-4086-89ae-28909368ddb5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 16.1 years (5,890 days).

Biospecimens (3 samples)
- Sample 0DPX36: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPX3G, 0DPX41 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
